Somatic mutation profile of tumor specimen ASCProject_0006_T2_WES (aliquot ASCProject_0006_T2_WES_1) from CMI case ASCProject_0006, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 29.9 years (10,916 days).
Specimen ASCProject_0006_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e121180f-a076-45ca-9740-dbf9080a67fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0006_BLOOD_Normal (Buffy Coat), aliquot ASCProject_0006_BLOOD_Normal_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46d0dfb7-001c-4dce-9eff-fc24cb2a640c

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Intron 5, Silent 4, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY3 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 33/192 reads (17%) | catalogued as COSV53167237; called by muse, mutect2, varscan2
- ANXA11 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs139186583; called by muse, mutect2, varscan2
- CNTNAP1 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs948880576, COSV52854005; called by muse, mutect2, varscan2
- COL6A6 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.716); catalogued as rs1412875334; called by muse, mutect2
- FAM83G | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs563466170, COSV100524818; called by muse, mutect2, varscan2
- KCNF1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs745849015, COSV54462436; called by muse, mutect2, varscan2
- PCDHB13 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 35/510 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1311241816, COSV99506551; called by muse, mutect2
- PFKFB2 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 44/210 reads (21%) | PolyPhen benign (0.409); catalogued as rs776741129; called by muse, mutect2, varscan2
- SERINC2 | c.694G>A p.G232S (on ENST00000373709 / NM_178865.5; = p.G236S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs184672093, COSV65491629; called by muse, mutect2, varscan2
- SI | c.4955C>T p.P1652L | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017824; called by muse, mutect2, varscan2
- VWA3A | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs543407642; called by muse, mutect2, varscan2
- APBA2 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARID1A | c.3855T>A p.Y1285* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- CNBD2 | c.654C>G p.F218L | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- FMO4 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- FOXE3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2
- GRK3 | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- KDM4A | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIR3DL3 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LEMD3 | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.047); called by muse, mutect2
- MED12 | c.88_90del p.K30del | In Frame Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.1750A>G p.R584G | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PKHD1 | c.3726A>C p.L1242F | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- POGLUT1 | c.927_931del p.H310Yfs*21 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | called by mutect2, pindel, varscan2
- RASA1 | c.3010_3011del p.A1004Sfs*4 | Frame Shift Del (DEL) | VAF 103/471 reads (22%) | called by mutect2, pindel, varscan2
- TBC1D25 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 109/409 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TENT5C | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TIAM1 | c.1861T>C p.F621L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDHR1 | c.984G>A p.A328= | Silent (SNP) | VAF 50/217 reads (23%) | catalogued as rs368242294; called by muse, mutect2, varscan2
- FAM171A1 | c.486C>T p.Y162= | Silent (SNP) | VAF 64/296 reads (22%) | called by muse, mutect2, varscan2
- PABPC3 | c.1710T>C p.P570= | Silent (SNP) | VAF 68/332 reads (20%) | called by muse, mutect2, varscan2
- SLC25A48 | c.555G>T p.L185= (on ENST00000650267; = p.L131= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2, varscan2
- CCDC173 | c.68-72G>A | Intron (SNP) | VAF 36/162 reads (22%) | catalogued as rs754370821; called by muse, mutect2, varscan2
- EIF5A | c.165+417C>T | Intron (SNP) | VAF 60/286 reads (21%) | catalogued as rs530996423; called by muse, mutect2, varscan2
- GALNT13 | c.1396-789C>T | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- GALNT13 | c.1396-788C>T | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- LSP1 | c.54-13400C>T | Intron (SNP) | VAF 17/104 reads (16%) | catalogued as rs965981480, COSV61133448; called by muse, mutect2, varscan2
